Somatic mutation profile of tumor specimen TCGA-RD-A7BT-01A (aliquot TCGA-RD-A7BT-01A-11D-A33T-08) from TCGA case TCGA-RD-A7BT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.0 years (24,107 days).
Specimen TCGA-RD-A7BT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98f9302d-fc6a-4691-9edb-b44d2088991f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A7BT-10A (Blood Derived Normal), aliquot TCGA-RD-A7BT-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73b4138f-ac42-41a6-b560-7ee53388c02d

The open-access MAF lists 245 somatic variants for this specimen: 191 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 47, Nonsense Mutation 6, Splice Region 4, Intron 4, Frame Shift Del 3, Nonstop Mutation 2, RNA 1, 3'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.3047C>G p.S1016* (on ENST00000502732 / NM_007314.4; = p.S1001* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as COSV100773098; called by muse, mutect2, varscan2
- ACAN | c.4251A>C p.E1417D | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as COSV100719409; called by muse, varscan2
- ACBD5 | c.1259G>C p.G420A (on ENST00000375888 / NM_001352568.1; = p.G411A on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV101022696; called by muse, mutect2, varscan2
- AFF3 | c.2729C>G p.S910* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100420247; called by muse, mutect2, varscan2
- ALKBH6 | c.143C>G p.P48R (on ENST00000252984 / NM_001297701.2; = p.P76R on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99431347; called by muse, mutect2
- AMY2B | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1557770704, COSV100796537; called by muse, mutect2, varscan2
- ANK2 | c.5036G>C p.G1679A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as COSV100004565, COSV52164394; called by muse, mutect2, varscan2
- ANKRD29 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV52426419; called by muse, mutect2, varscan2
- APOL3 | c.938G>A p.R313Q (on ENST00000349314 / NM_145640.2; = p.R242Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773872410, COSV62580362; called by muse, mutect2, varscan2
- ARHGAP32 | c.4766C>T p.P1589L (on ENST00000310343 / NM_001378025.1; = p.P1240L on NM_014715.4) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs867755185, COSV100089564; called by muse, mutect2, varscan2
- ARHGAP45 | c.1732A>G p.S578G | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100491200; called by muse, mutect2, varscan2
- ARHGEF17 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV99737000; called by muse, mutect2, varscan2
- ARPP21 | c.2218C>G p.Q740E | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99493607; called by muse, mutect2, varscan2
- ASB10 | c.1301G>A p.R434H (on ENST00000420175 / NM_001142459.2; = p.R419H on NM_080871.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758074125, COSV52001248; called by mutect2, varscan2
- ASTN1 | c.2075T>G p.L692R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99920060; called by muse, mutect2, varscan2
- ATP2B4 | c.830A>C p.N277T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100398123; called by muse, mutect2, varscan2
- ATP6V0A1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311497633, COSV52870890; called by muse, mutect2
- B4GALNT1 | c.381G>C p.S127= | Splice Region (SNP) | VAF 36/250 reads (14%) | catalogued as COSV100356560; called by muse, mutect2, varscan2
- BCLAF3 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV100503421; called by muse, mutect2, varscan2
- BMP4 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.519); catalogued as COSV99817176; called by muse, mutect2, varscan2
- BPTF | c.4964A>G p.N1655S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100076202; called by muse, mutect2, varscan2
- BRINP3 | c.1633A>C p.S545R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100819579, COSV66524852; called by muse, mutect2, varscan2
- C19orf18 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.186); catalogued as COSV100072064; called by muse, mutect2, varscan2
- CCDC178 | c.2082C>A p.N694K (on ENST00000383096 / NM_001105528.3; = p.N656K on NM_198995.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100287132; called by muse, mutect2
- CCDC60 | c.1041-2A>G p.X347_splice | Splice Site (SNP) | VAF 36/207 reads (17%) | catalogued as COSV100555811; called by muse, mutect2, varscan2
- CCR3 | c.467T>G p.V156G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100656801; called by muse, mutect2
- CCR3 | c.469A>C p.T157P | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100656802; called by muse, mutect2
- CD33 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV51803829, COSV99220844; called by muse, mutect2
- CDH9 | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV99160200; called by muse, mutect2, varscan2
- CHPF | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99705373; called by muse, mutect2, varscan2
- CILP | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs201015610, COSV56025993; called by muse, mutect2, varscan2
- CMYA5 | c.5618A>G p.K1873R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV101484426; called by muse, mutect2, varscan2
- CNGA4 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66005440; called by muse, mutect2
- CNN3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV99598717; called by muse, mutect2, varscan2
- CNOT3 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV99652384; called by muse, mutect2, varscan2
- CNTN3 | c.1250A>C p.K417T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99726284; called by muse, mutect2, varscan2
- CNTN5 | c.1848C>A p.F616L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); catalogued as COSV54289979, COSV99682052; called by muse, mutect2, varscan2
- COL11A1 | c.5421A>C p.*1807Yext*2 | Nonstop Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV62181777; called by muse, mutect2, varscan2
- COL21A1 | c.425T>G p.L142R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99780502; called by muse, mutect2, varscan2
- COL9A1 | c.1868T>G p.L623R | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.599); catalogued as COSV100295776; called by muse, mutect2
- CRNN | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 89/351 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99664452; called by muse, mutect2, varscan2
- CSMD3 | c.9545G>T p.G3182V (on ENST00000297405 / NM_001363185.1; = p.G3013V on NM_052900.3) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850031; called by muse, mutect2, varscan2
- DAAM2 | c.2422T>G p.F808V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV99227404; called by muse, mutect2, varscan2
- DCLK2 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99651559; called by muse, mutect2, varscan2
- DMD | c.8450T>G p.L2817R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58914465; called by muse, mutect2, varscan2
- DOCK10 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs372497608; called by muse, mutect2, varscan2
- DOCK2 | c.3669C>G p.Y1223* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99916011; called by muse, mutect2, varscan2
- DSCAM | c.4535A>C p.E1512A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV101261681; called by muse, mutect2, varscan2
- DUSP19 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs145225950, COSV100700343; called by muse, mutect2, varscan2
- EDNRB | c.1168A>T p.M390L (on ENST00000377211 / NM_001201397.1; = p.M300L on NM_000115.5) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100527177; called by muse, mutect2
- EGFR | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51849115, COSV99295752; called by muse, mutect2
- EIF2B2 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99837791; called by muse, mutect2, varscan2
- EMC7 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99855017; called by muse, mutect2, varscan2
- FAAP24 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV54289023, COSV99579120; called by muse, mutect2, varscan2
- FAM47C | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV63723950; called by muse, mutect2, varscan2
- FAT4 | c.14622A>C p.Q4874H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58672325, COSV58674006, COSV58679733; called by muse, mutect2, varscan2
- FCGBP | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157390258; called by muse, mutect2, varscan2
- FOXC2 | c.1316C>G p.T439R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs1266309492, COSV100234423; called by muse, mutect2, varscan2
- FREM2 | c.5289T>G p.N1763K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV99751361; called by muse, mutect2, varscan2
- FSTL4 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV99533959; called by muse, mutect2, varscan2
- GNGT1 | c.110G>C p.C37S | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV99949884; called by muse, mutect2
- GPLD1 | c.425T>G p.L142R | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388046276, COSV100015620; called by muse, mutect2, varscan2
- GRM8 | c.2467A>G p.S823G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1378227870, COSV58822677, COSV58854679; called by muse, mutect2, varscan2
- HGD | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV52198118; called by muse, mutect2, varscan2
- IFT172 | c.2254C>A p.Q752K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99563539; called by muse, mutect2, varscan2
- ISM1 | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV52605432; called by muse, varscan2
- KCNH1 | c.857T>C p.L286P | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55069756, COSV55079390, COSV99661871; called by muse, mutect2, varscan2
- KCTD16 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV101568908; called by muse, mutect2, varscan2
- KDM1A | c.597T>G p.I199M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100752883; called by muse, mutect2, varscan2
- KRT74 | c.1288A>T p.S430C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59773998, COSV99977715; called by muse, mutect2, varscan2
- KRTAP10-11 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs782557322, COSV58177428; called by muse, mutect2, varscan2
- LIFR | c.1638T>G p.S546R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99665694; called by muse, mutect2, varscan2
- LIG1 | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV99619409; called by muse, mutect2, varscan2
- LRP1B | c.10756A>C p.S3586R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV67242427; called by muse, mutect2, varscan2
- LUZP2 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186534695, COSV100421617; called by muse, mutect2, varscan2
- LY75-CD302 | c.5622A>C p.*1874Yext*? | Nonstop Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs1346939051, COSV99374197; called by muse, mutect2, varscan2
- MAGEC1 | c.3140T>G p.V1047G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV99596715; called by muse, mutect2, varscan2
- MED13 | c.3067G>C p.G1023R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV101181464; called by muse, mutect2, varscan2
- MITF | c.459A>C p.Q153H (on ENST00000448226 / NM_006722.3; = p.Q47H on NM_000248.4) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV100097515; called by muse, mutect2, varscan2
- MKRN3 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180324511, COSV58811586; called by muse, mutect2, varscan2
- MLKL | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372403777; called by muse, mutect2, varscan2
- MRPS14 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100871574; called by muse, mutect2, varscan2
- MTHFD1L | c.2236G>C p.A746P | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66225338, COSV66225884; called by muse, mutect2, varscan2
- MTNR1B | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs774779129, COSV57065124; called by muse, mutect2, varscan2
- MXRA5 | c.8336T>A p.V2779D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99479656; called by muse, mutect2, varscan2
- MYF5 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953433; called by muse, mutect2, varscan2
- MYO16 | c.1388G>C p.G463A | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99194799; called by muse, mutect2
- MYO16 | c.3583A>C p.T1195P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100697516; called by muse, mutect2, varscan2
- N4BP2 | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99789355; called by muse, mutect2, varscan2
- NBEA | c.6994T>G p.L2332V | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100079789; called by muse, mutect2, varscan2
- NEDD4 | c.1999C>T p.R667W (on ENST00000508342 / NM_001284338.1; = p.R248W on NM_006154.4) | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs777969350, COSV100164195; called by muse, mutect2, varscan2
- NHS | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs748302530, COSV101197046; called by muse, mutect2, varscan2
- NIPAL3 | c.924G>A p.L308= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as COSV99135626; called by muse, mutect2, varscan2
- NIPBL | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99243010; called by muse, mutect2, varscan2
- NPAP1 | c.880A>C p.I294L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV100276311; called by muse, mutect2, varscan2
- NPBWR2 | c.623G>C p.W208S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871125, COSV100871155; called by muse, mutect2, varscan2
- NRK | c.3329A>C p.N1110T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99689346; called by muse, mutect2, varscan2
- NTRK3 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58125113, COSV58140678; called by muse, mutect2, varscan2
- OR10J1 | c.779A>T p.K260M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV101419893, COSV101420054, COSV71128324; called by muse, mutect2, varscan2
- OR10J1 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101420055; called by muse, mutect2, varscan2
- OR10R2 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV100936853; called by muse, mutect2, varscan2
- OR14C36 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100507595; called by muse, mutect2, varscan2
- OR1D2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100514022; called by muse, mutect2, varscan2
- OR2T33 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100532338; called by muse, varscan2
- OR2W3 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100831871; called by muse, mutect2, varscan2
- OR4C3 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100168370; called by muse, mutect2, varscan2
- OR4K17 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59647915; called by muse, mutect2, varscan2
- OR51A7 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63788151; called by muse, mutect2, varscan2
- OR51F1 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR5B17 | c.629T>G p.L210R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV100641972, COSV62159848; called by muse, mutect2, varscan2
- ORM2 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99407715; called by muse, varscan2
- PAX6 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 21/201 reads (10%) | catalogued as CM030487, COSV99570858; called by muse, varscan2
- PCDHGA12 | c.1478A>C p.E493A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV99342700; called by muse, mutect2, varscan2
- PCLO | c.11206A>C p.T3736P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as COSV100438812; called by muse, mutect2
- PDE1C | c.243G>A p.R81= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100374065; called by muse, mutect2, varscan2
- PLA2G7 | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99221634; called by muse, mutect2, varscan2
- PLCD1 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.069); catalogued as COSV99379339; called by muse, mutect2, varscan2
- PLEKHG3 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99907232; called by muse, mutect2, varscan2
- PLEKHG5 | c.197C>T p.P66L (on ENST00000400915 / NM_001042663.3; = p.P29L on NM_020631.6) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998963899, COSV100557199; ClinVar: uncertain significance; called by muse, varscan2
- PLK1 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99892621; called by muse, mutect2
- POM121L12 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.633); catalogued as COSV68693368; called by muse, mutect2, varscan2
- PON1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99731862; called by muse, mutect2, varscan2
- PPFIA4 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99830591; called by muse, mutect2, varscan2
- PPP1R3A | c.1704A>C p.E568D | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99494545; called by muse, mutect2, varscan2
- PSMB11 | c.15T>A p.D5E | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101273654; called by muse, mutect2, varscan2
- PSPC1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100142743; called by muse, mutect2, varscan2
- PTPRT | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs146000056, COSV104421190, COSV62033736; called by muse, mutect2, varscan2
- RAPGEF3 | c.916G>A p.E306K (on ENST00000389212; = p.E264K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1441602024, COSV99406958; called by muse, mutect2, varscan2
- RBP3 | c.2763C>A p.S921R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs548622709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPS1 | c.1847C>T p.T616I (on ENST00000450536 / NM_001286611.2; = p.T615I on NM_031922.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99239098; called by muse, mutect2, varscan2
- RGS18 | c.93A>C p.E31D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as COSV100817847, COSV66509361, COSV66510145; called by muse, mutect2, varscan2
- RNF207 | c.1679C>G p.S560* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100658353; called by muse, mutect2, varscan2
- ROBO1 | c.1306A>C p.S436R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101459507; called by muse, mutect2, varscan2
- ROCK2 | c.1613A>T p.D538V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV99837962; called by muse, mutect2, varscan2
- RPE65 | c.1576T>G p.F526V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99254354; called by muse, mutect2, varscan2
- RSRC1 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99905891, COSV99907311; called by muse, mutect2, varscan2
- SACS | c.6083A>C p.E2028A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV101207781; called by muse, mutect2, varscan2
- SALL1 | c.321A>C p.Q107H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV51755249; called by muse, mutect2, varscan2
- SAMD9 | c.2185A>C p.S729R | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101180386; called by muse, mutect2, varscan2
- SCG2 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as rs1462019509, COSV59539101; called by muse, mutect2, varscan2
- SCN11A | c.3574T>G p.F1192V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100182793; called by muse, mutect2, varscan2
- SCN9A | c.2432T>A p.F811Y (on ENST00000303354; = p.F800Y on NM_002977.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV100314447, COSV57599792; called by mutect2, varscan2
- SELPLG | c.605A>C p.Q202P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99947754; called by muse, mutect2, varscan2
- SHROOM4 | c.1578A>C p.Q526H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99174859; called by muse, mutect2, varscan2
- SLC17A3 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100399438; called by muse, mutect2, varscan2
- SLC6A18 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as COSV99722727; called by muse, mutect2
- SLCO6A1 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101135100; called by muse, varscan2
- SLITRK1 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101000089; called by muse, mutect2, varscan2
- SNIP1 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as COSV99953321; called by muse, mutect2, varscan2
- SORL1 | c.2593T>A p.F865I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52764511, COSV99495710; called by muse, mutect2, varscan2
- SPRED3 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612795, COSV58312955; called by muse, mutect2, varscan2
- SSUH2 | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100436192; called by muse, mutect2, varscan2
- ST3GAL6 | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV54580153, COSV54581667; called by muse, mutect2, varscan2
- SYNE1 | c.21713T>G p.L7238R (on ENST00000367255 / NM_182961.4; = p.L7167R on NM_033071.3) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99582043; called by muse, mutect2
- SYT7 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99802258; called by muse, mutect2, varscan2
- TDRD6 | c.4980A>C p.E1660D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV100288460; called by muse, mutect2, varscan2
- TFAP2B | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53831959; called by muse, mutect2, varscan2
- THSD7B | c.3701A>C p.K1234T (on ENST00000272643; = p.K1232T on NM_001316349.2) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1360239886, COSV55662801; called by muse, mutect2, varscan2
- TNFRSF10A | c.831G>A p.R277= | Splice Region (SNP) | VAF 16/165 reads (10%) | catalogued as COSV99646102; called by muse, mutect2, varscan2
- TNFRSF11B | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99817049; called by muse, mutect2, varscan2
- TNS2 | c.527T>G p.F176C (on ENST00000314250 / NM_170754.4; = p.F186C on NM_015319.2) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100048752; called by muse, mutect2, varscan2
- TPTE2 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55019875; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1855C>A p.Q619K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV100967119; called by muse, mutect2, varscan2
- TRPC5 | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV53288279; called by muse, mutect2, varscan2
- TRPC6 | c.427A>C p.N143H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723786; called by muse, mutect2, varscan2
- TTN | c.81903A>C p.K27301N (on ENST00000591111; = p.K19877N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | PolyPhen possibly damaging (0.856); catalogued as COSV59884065; called by muse, mutect2
- TTN | c.41495T>G p.L13832R (on ENST00000591111; = p.L6408R on NM_003319.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100590614, COSV100594174; called by muse, mutect2, varscan2
- TTN | c.5342A>C p.N1781T (on ENST00000591111; = p.N1735T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | PolyPhen probably damaging (0.995); catalogued as COSV100633487; called by muse, mutect2, varscan2
- TWNK | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99273294; called by muse, mutect2, varscan2
- TYR | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54470967, COSV99633214; called by muse, mutect2, varscan2
- USH2A | c.3463A>C p.S1155R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs766609270, COSV56372284; called by muse, mutect2, varscan2
- ZEB2 | c.2512A>C p.K838Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV100357079; called by muse, mutect2, varscan2
- ZFHX4 | c.7936A>T p.K2646* | Nonsense Mutation (SNP) | VAF 38/71 reads (54%) | catalogued as COSV99268580; called by muse, mutect2, varscan2
- ZFP28 | c.846A>T p.Q282H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100019935; called by muse, mutect2, varscan2
- ZIM2 | c.819C>A p.D273E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs776797607, COSV99690680; called by muse, mutect2, varscan2
- ZNF24 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99734445; called by muse, mutect2, varscan2
- ZNF251 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV99478926; called by muse, mutect2, varscan2
- ZNF471 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV100340759, COSV100340922; called by muse, mutect2, varscan2
- ZNF559 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV100416785; called by muse, mutect2, varscan2
- ZNF571 | c.164A>T p.K55M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100144021, COSV100144045; called by muse, mutect2, varscan2
- ZNF578 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101405127; called by muse, mutect2, varscan2
- ZNF606 | c.1994G>T p.C665F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV100072065; called by muse, mutect2, varscan2
- ZNF98 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100757567, COSV63334161; called by muse, mutect2, varscan2
- ZP4 | c.1515A>C p.K505N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as COSV63910816, COSV63911657; called by muse, mutect2, varscan2
- ATXN1 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR8G2P | c.509A>T p.K170M | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- RFC5 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- SIPA1L1 | c.1823del p.N608Tfs*6 | Frame Shift Del (DEL) | VAF 96/192 reads (50%) | called by mutect2, pindel, varscan2
- SYNRG | c.2943A>T p.E981D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TOPORS | c.1521_1524del p.Y507* | Frame Shift Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- TRPM3 | c.2288_2303del p.D763Gfs*12 (on ENST00000357533 / NM_001366142.2; = p.D606Gfs*12 on NM_020952.6) | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel
- ABCA13 | c.10038T>G p.T3346= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV101446738, COSV101446901; called by muse, mutect2, varscan2
- AFG3L2 | c.327A>G p.G109= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV99302237; called by muse, mutect2, varscan2
- ANGPTL3 | c.1321T>C p.L441= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99226221; called by muse, mutect2, varscan2
- ANK2 | c.5544A>C p.S1848= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as COSV100004567; called by muse, mutect2, varscan2
- CACNA1I | c.1050C>A p.I350= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60805686; called by muse, mutect2, varscan2
- CCL2 | c.27C>T p.C9= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1344709763, COSV99861599; called by muse, mutect2, varscan2
- CNTNAP4 | c.2043T>C p.T681= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100273629, COSV56662212; called by muse, mutect2
- CTSO | c.888A>G p.G296= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV70809474; called by muse, mutect2, varscan2
- DNAH11 | c.4591T>C p.L1531= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60937060; called by muse, mutect2, varscan2
- DNAH8 | c.1878A>C p.A626= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100547360; called by muse, mutect2, varscan2
- FAM102A | c.969G>T p.R323= (on ENST00000373095 / NM_001035254.3; = p.R181= on NM_203305.2) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100305637; called by muse, mutect2, varscan2
- FRY | c.765G>A p.R255= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1365561754, COSV100968793; called by muse, mutect2, varscan2
- GLS2 | c.1176C>G p.L392= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100358503; called by muse, mutect2, varscan2
- GREB1 | c.1293C>T p.P431= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs754541833, COSV99303958; called by muse, mutect2, varscan2
- GRK4 | c.399G>C p.L133= (on ENST00000398052 / NM_182982.3; = p.L101= on NM_005307.3) | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV100584317; called by muse, mutect2, varscan2
- GSTM4 | c.471T>C p.D157= | Silent (SNP) | VAF 146/386 reads (38%) | catalogued as COSV100264326, COSV58695926; called by muse, mutect2, varscan2
- HIVEP3 | c.4701T>G p.P1567= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99914204; called by muse, mutect2, varscan2
- IRF2BPL | c.2358G>C p.G786= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99468533; called by muse, mutect2
- ITGAX | c.2319C>T p.A773= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1016765276, COSV51642692; called by muse, mutect2, varscan2
- KHDC3L | c.387G>A p.Q129= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV100950466; called by muse, mutect2, varscan2
- KIAA0319 | c.465G>A p.E155= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV100985849; called by muse, mutect2, varscan2
- LEPR | c.1956T>C p.D652= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1164204099, COSV100756819; called by muse, mutect2, varscan2
- LPAR5 | c.435G>A p.V145= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100321125; called by muse, mutect2
- MICALL2 | c.1410G>A p.A470= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1424334334, COSV99876324; called by muse, mutect2, varscan2
- NFIX | c.1122G>A p.T374= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1325236991, COSV100666660; called by muse, mutect2, varscan2
- NPY2R | c.954T>G p.T318= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100279960, COSV100279996; called by muse, mutect2, varscan2
- OR13C9 | c.576C>T p.I192= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1233405909, COSV99403581; called by muse, mutect2
- OR4A16 | c.274T>C p.L92= | Silent (SNP) | VAF 25/252 reads (10%) | catalogued as COSV100125435; called by muse, mutect2, varscan2
- OR52D1 | c.57G>A p.G19= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100495117; called by muse, mutect2, varscan2
- OR5M8 | c.444T>C p.Y148= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV100510803; called by muse, varscan2
- PCLO | c.7737T>G p.T2579= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as COSV61653555; called by muse, mutect2
- PGBD1 | c.816A>G p.Q272= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV99461017; called by muse, mutect2, varscan2
- PLAT | c.438C>T p.A146= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs536186900, COSV99535473; called by muse, mutect2, varscan2
- POLR3A | c.4137C>T p.F1379= | Silent (SNP) | VAF 26/192 reads (14%) | catalogued as rs763935868, COSV100965820; called by muse, mutect2, varscan2
- PPP1R3A | c.1161T>C p.D387= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV99494551; called by muse, mutect2, varscan2
- PREX2 | c.3291T>C p.S1097= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV99910415; called by muse, mutect2, varscan2
- PTPRC | c.1140C>T p.N380= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs200643724; ClinVar: likely benign; called by muse, mutect2, varscan2
- PWWP3B | c.765A>G p.K255= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV61800188; called by muse, mutect2
- RTL3 | c.216A>G p.A72= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100330157; called by muse, mutect2, varscan2
- SF3B2 | c.1698C>T p.I566= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs762998339, COSV100488448; called by muse, mutect2, varscan2
- TIGD5 | c.1677G>A p.P559= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs777570173, COSV99643714; called by muse, mutect2, varscan2
- TRAK1 | c.1143G>A p.T381= (on ENST00000327628 / NM_001349247.2; = p.T323= on NM_014965.5) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs764329895, COSV100410378, COSV58266192; called by muse, mutect2, varscan2
- TTN | c.16572T>G p.T5524= (on ENST00000591111; = p.T4597= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV100633486; called by muse, mutect2
- UBQLN3 | c.1074T>G p.T358= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV100293278, COSV61163164; called by muse, mutect2, varscan2
- VDR | c.28C>T p.L10= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99969042; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.519T>C p.T173= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV58672625, COSV58672983; called by muse, mutect2, varscan2
- ZNF683 | c.858G>T p.L286= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100853753, COSV100853761; called by muse, mutect2, varscan2
- ADH1B | c.19-78G>A | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65823G>C | Intron (SNP) | VAF 23/204 reads (11%) | catalogued as COSV99720415; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120942 C>A | 3'Flank (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- OR8G5 | c.-3A>G | 5'UTR (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100422704; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-48014A>C | Intron (SNP) | VAF 13/38 reads (34%) | catalogued as COSV67442844; called by muse, mutect2
- SSPOP | n.2640C>T | RNA (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100022930, COSV100023063, COSV50488091; called by muse, mutect2, varscan2
- TRIM55 | c.1524+1323T>G | Intron (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99397295; called by muse, mutect2, varscan2
